Somatic mutation profile of tumor specimen C3N-02433-01 (aliquot CPT0147380010) from CPTAC case C3N-02433, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.8 years (25,140 days).
Specimen C3N-02433-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abc5ca20-877d-4445-a411-487810cdee22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02433-71 (Blood Derived Normal), aliquot CPT0147410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd866dc0-17ea-49e0-8e88-4cffdb51f571

The open-access MAF lists 60 somatic variants for this specimen: 36 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 19, Nonsense Mutation 4, Intron 3, 3'UTR 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 231/656 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BCL11A | c.1733C>A p.S578* (on ENST00000335712 / NM_001365609.1; = p.S612* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV59628036; called by muse, mutect2, varscan2
- CCDC88A | c.3241G>T p.A1081S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.034); catalogued as COSV55056992; called by muse, mutect2, varscan2
- CLCN4 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101073590; called by muse, mutect2, varscan2
- CWF19L1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs751964727; called by muse, mutect2
- LRRC6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1360636907, COSV51544947; called by muse, mutect2, varscan2
- NOX4 | c.1516-4G>A | Splice Region (SNP) | VAF 11/58 reads (19%) | catalogued as rs540624041; called by muse, mutect2, varscan2
- PDE4D | c.1768G>A p.E590K (on ENST00000340635 / NM_001104631.2; = p.E454K on NM_006203.4) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57719765; called by muse, mutect2, varscan2
- RSPO4 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 27/377 reads (7%) | catalogued as COSV99448978; called by muse, mutect2
- TANC2 | c.4990A>G p.I1664V | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs370440994; called by muse, mutect2, varscan2
- AEBP2 | c.209del p.G70Afs*71 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- ARID1B | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, varscan2
- BYSL | c.1262T>G p.L421R | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCT4 | c.71A>C p.Y24S | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CD109 | c.472A>C p.K158Q | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CDH5 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.278); called by muse, mutect2
- CNNM2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 145/770 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DNAH9 | c.10388C>G p.P3463R | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EIF3G | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- ELMOD1 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- EXOC3 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- GNA13 | c.1106A>G p.D369G | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.646); called by muse, mutect2
- GSPT2 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- MAP7D3 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC5B | c.13181A>G p.E4394G | Missense Mutation (SNP) | VAF 94/594 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- MYO1E | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PFN4 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- POLR2A | c.2942G>A p.C981Y | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- RHCG | c.499T>G p.F167V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, varscan2
- SHB | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- SPZ1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TCEAL5 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 20/427 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2
- TOX3 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 32/629 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2
- ZBTB5 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF23 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZNF800 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ARC | c.987G>A p.L329= | Silent (SNP) | VAF 64/237 reads (27%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.516A>T p.S172= | Silent (SNP) | VAF 63/300 reads (21%) | called by muse, mutect2, varscan2
- CLCF1 | c.162C>T p.L54= | Silent (SNP) | VAF 65/243 reads (27%) | called by muse, mutect2, varscan2
- COL20A1 | c.313C>T p.L105= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs377096032; called by muse, mutect2, varscan2
- COL6A6 | c.1179C>T p.F393= | Silent (SNP) | VAF 28/300 reads (9%) | catalogued as rs202062422; called by muse, mutect2
- CRB1 | c.3384C>T p.I1128= | Silent (SNP) | VAF 17/303 reads (6%) | called by muse, mutect2
- CYP1A2 | c.537G>A p.L179= | Silent (SNP) | VAF 17/239 reads (7%) | catalogued as COSV59659509; called by muse, mutect2
- EPS8L3 | c.285C>T p.S95= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs1389588873; called by muse, mutect2
- HDGFL2 | c.1809T>C p.N603= | Silent (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- IGFBP5 | c.774C>T p.D258= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs751579385; called by muse, mutect2, varscan2
- IGHV1-58 | c.352G>A p.*118= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- MBOAT7 | c.54C>T p.I18= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- MYCBP2 | c.4935C>G p.L1645= (on ENST00000357337; = p.L1683= on NM_015057.5) | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs574817467, COSV100631051, COSV62009798; called by muse, mutect2
- NCOR1 | c.6411A>C p.P2137= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV51962016; called by muse, mutect2, varscan2
- OR2M7 | c.336C>T p.C112= | Silent (SNP) | VAF 45/331 reads (14%) | called by muse, mutect2, varscan2
- OR8B12 | c.816G>T p.V272= | Silent (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- PRR16 | c.99C>T p.I33= | Silent (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- RPL7L1 | c.129A>T p.A43= | Silent (SNP) | VAF 57/293 reads (19%) | called by muse, mutect2, varscan2
- VAPA | c.729T>C p.F243= (on ENST00000400000 / NM_194434.3; = p.F288= on NM_003574.6) | Silent (SNP) | VAF 24/95 reads (25%) | called by mutect2, varscan2
- CDHR2 | c.2807-17C>A | Intron (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- EFHC1 | c.*345T>C | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ENY2 | c.230-696dup | Intron (INS) | VAF 47/189 reads (25%) | called by mutect2, pindel, varscan2
- EPHB6 | c.1751-14G>A | Intron (SNP) | VAF 19/463 reads (4%) | catalogued as rs1435548372; called by muse, mutect2
- VPS37C | c.*902C>T | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
